Somatic mutation profile of tumor specimen TCGA-D3-A5GT-01A (aliquot TCGA-D3-A5GT-01A-12D-A30X-08) from TCGA case TCGA-D3-A5GT, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 43.7 years (15,960 days).
Specimen TCGA-D3-A5GT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e09e09a-3a8a-4f4d-afbe-b9a63c1413f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A5GT-10A (Blood Derived Normal), aliquot TCGA-D3-A5GT-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f8ec88e-0ed7-4aec-afe9-ed054c742510

The open-access MAF lists 29 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 5, Nonsense Mutation 2, Frame Shift Del 2, Frame Shift Ins 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/127 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABI3BP | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as rs750938732, COSV52527991; called by muse, mutect2, varscan2
- ADGRL3 | c.3962C>T p.A1321V (on ENST00000506720 / NM_001322402.2; = p.A1210V on NM_015236.6) | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as COSV72230723; called by muse, mutect2, varscan2
- ANO7 | c.1922C>T p.A641V (on ENST00000274979; = p.A587V on NM_001370694.2) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51472472; called by muse, mutect2, varscan2
- APOB | c.4267G>A p.D1423N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.773); catalogued as rs911750784, COSV51937597; called by muse, mutect2, varscan2
- CACNG8 | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as COSV54414929; called by muse, mutect2, varscan2
- CNGA3 | c.977A>G p.K326R | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as COSV55624730; called by muse, mutect2, varscan2
- ELN | c.1072G>T p.G358W | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT deleterious, low confidence (0); catalogued as COSV52710759; called by muse, mutect2, varscan2
- GSAP | c.2501A>G p.N834S | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV57530385; called by muse, mutect2
- IFNL1 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); catalogued as rs370981133; called by muse, mutect2, varscan2
- KIF24 | c.3791C>G p.A1264G | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV52659182; called by muse, mutect2, varscan2
- LACC1 | c.13G>T p.V5F | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1462532910, COSV57829170; called by muse, mutect2, varscan2
- NDOR1 | c.891C>G p.H297Q | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV61287993; called by muse, mutect2, varscan2
- PIPOX | c.832G>T p.A278S | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.189); catalogued as COSV60141900, COSV60142507; called by muse, mutect2, varscan2
- PLXNA4 | c.1503+1G>A p.X501_splice | Splice Site (SNP) | VAF 73/152 reads (48%) | catalogued as COSV58130498; called by muse, mutect2, varscan2
- RBM46 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 24/47 reads (51%) | catalogued as COSV55979322; called by muse, mutect2, varscan2
- RBM48 | c.819A>T p.R273S | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56002840; called by muse, mutect2, varscan2
- RPRD2 | c.447_448insTTTT p.K150Ffs*2 | Frame Shift Ins (INS) | VAF 4/18 reads (22%) | catalogued as COSV100954690; called by mutect2, varscan2
- SLC35E4 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs368736019; called by muse, mutect2, varscan2
- SORCS2 | c.2779C>T p.R927W | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.65); catalogued as rs199942882, COSV61170906; called by muse, mutect2, varscan2
- TET1 | c.2383A>G p.K795E | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV65385136; called by muse, mutect2, varscan2
- GUCA1A | c.468del p.F156Lfs*2 | Frame Shift Del (DEL) | VAF 9/92 reads (10%) | called by mutect2, pindel
- KCNB2 | c.2452_2464del p.L818Gfs*24 | Frame Shift Del (DEL) | VAF 14/98 reads (14%) | called by mutect2, pindel, varscan2
- ARHGEF40 | c.279A>G p.A93= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs763770134, COSV53880825; called by muse, mutect2, varscan2
- DDB1 | c.2457C>T p.C819= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as COSV57103132; called by muse, mutect2, varscan2
- EEFSEC | c.1758C>T p.F586= | Silent (SNP) | VAF 39/75 reads (52%) | catalogued as rs375142488; called by muse, mutect2, varscan2
- PAPPA | c.4446C>T p.N1482= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs144490263; called by muse, mutect2, varscan2
- TTN | c.80763G>T p.V26921= (on ENST00000591111; = p.V19497= on NM_003319.4) | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV60099325; called by muse, mutect2, varscan2
- OR2W5 | n.646G>A | RNA (SNP) | VAF 17/77 reads (22%) | catalogued as rs145704231; called by muse, mutect2, varscan2
